TCGA case TCGA-55-7815 — Lung Adenocarcinoma (TCGA-LUAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung; Tissue source site: International Genomics Consortium. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/dd46c83e-6551-485b-b935-f3beed891244

Demographics
Sex at birth: male; Country of residence at enrollment: United States; Age at index: 76 years; Vital status: Alive.

Diagnoses (3)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C34.3; Tissue or organ of origin: Lower lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 77.0 years (28,119 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T2a; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage IB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Days to treatment start: 493 days (1.3 years); Days to treatment end: 585 days (1.6 years); Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 616 days (1.7 years); Days to treatment end: 616 days (1.7 years); Treatment outcome: Progressive Disease; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Chemotherapy; Days to treatment start: 706 days (1.9 years); Treatment outcome: Treatment Ongoing.
2. Recurrence of diagnosis 1 (Adenocarcinoma, NOS). Age at diagnosis: 78.3 years (28,585 days); Days to diagnosis: 466 days (1.3 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease; Surgery, NOS to Locoregional Site.
3. Metastasis of diagnosis 1 (Adenocarcinoma, NOS). Age at diagnosis: 78.6 years (28,711 days); Days to diagnosis: 592 days (1.6 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Surgery, NOS to Locoregional Site; Surgery, NOS to Distant Site.

Follow-up (4 entries)
- Days to follow up: 54 days; Disease response: Tumor Free.
- Day 466 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Days to recurrence: 466 days (1.3 years); Evidence of recurrence type: Convincing Image Source.
- Day 592 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Days to progression: 592 days (1.6 years).
- Days to follow up: 773 days (2.1 years); Disease response: With Tumor.

Other clinical attributes
- DLCO (% of predicted): 59; FEV1 after bronchodilator (% of reference): 76; FEV1 before bronchodilator (% of reference): 72.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-55-7815-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 0.7; Intermediate dimension: 0.7; Shortest dimension: 0.4.
  Slide TCGA-55-7815-01A-01-TS1: Section location: Top; Percent tumor nuclei: 80; Percent necrosis: 2; Percent lymphocyte infiltration: 15.
- Sample TCGA-55-7815-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-55-7815-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-55-7815-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1; Intermediate dimension: 0.6; Shortest dimension: 0.4.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Adenocarcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Tobacco smoking history indicator: 1; Anatomic organ subdivision: R-Lower; Pulmonary function test indicator: Yes.
- Drug treatment 1: Pharmaceutical therapy drug name: Chemo, NOS; Treatment best response: Clinical Progressive Disease.
- Radiation treatment: Treatment best response: Radiographic Progressive Disease.
- Follow-up form 1: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; New tumor event surgery: No; Tumor status: With tumor; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes.
- Follow-up form 1, New neoplasm event types: New tumor event type: Locoregional Recurrence.
- Follow-up form 1, Progression determined by list: New tumor event diagnosis evidence: Convincing Imaging.
- Follow-up form 2: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; New tumor event surgery: No; Tumor status: With tumor; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: Yes; New tumor event surgery met: No.
- Follow-up form 2, New neoplasm event types: New tumor event type: Distant Metastasis.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 773 days; disease-specific survival: no event (censored), 773 days; disease-free interval: event (new tumor event after initially disease-free), 466 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 466 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-55-7815-01A-11D-2166-01): tumor purity 0.29, ploidy 3.48, whole-genome doublings 1.
